Somatic mutation profile of tumor specimen 0DJVPR from CCDI case PBBXKW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 8.8 years (3,207 days).
Specimen 0DJVPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76fa1a52-25e4-43a5-b07a-3a56c660e741.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e3d1ea4-25ea-434b-b41f-822f143c5c76

The open-access MAF lists 63 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Intron 5, 5'UTR 5, Splice Site 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD2 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 86/657 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs972030736, COSV53950724; called by muse, mutect2, varscan2
- DNAH3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 58/583 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769073354, COSV54537817; called by muse, mutect2, varscan2
- HOXA2 | c.998G>T p.C333F | Missense Mutation (SNP) | VAF 101/937 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV56067260; called by muse, mutect2, varscan2
- KIF5A | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 78/736 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99672885, COSV99673698; called by muse, mutect2, varscan2
- KLRF1 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 42/677 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.06); catalogued as COSV99684304; called by muse, mutect2
- MAMSTR | c.625C>G p.R209G (on ENST00000318083 / NM_001130915.2; = p.R106G on NM_182574.2) | Missense Mutation (SNP) | VAF 39/438 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58882544; called by muse, mutect2
- NECAP2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 73/612 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61433698; called by muse, mutect2, varscan2
- PCDHB13 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 22/620 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53393831; called by muse, mutect2
- PCDHGB3 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 48/546 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305933236, COSV53998627, COSV54012470; called by muse, mutect2
- PDZRN4 | c.2350G>A p.G784R (on ENST00000402685 / NM_001164595.2; = p.G526R on NM_013377.4) | Missense Mutation (SNP) | VAF 60/756 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54203810; called by muse, mutect2
- PIK3AP1 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100226345; called by muse, mutect2
- RALGAPA1 | c.1430_1432del p.E477del | In Frame Del (DEL) | VAF 54/450 reads (12%) | catalogued as rs1227212510; called by pindel, varscan2
- REST | c.1406A>G p.E469G | Missense Mutation (SNP) | VAF 92/984 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1215291953; called by muse, mutect2
- RNF207 | c.1504C>G p.R502G | Missense Mutation (SNP) | VAF 52/574 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV65008420; called by muse, mutect2
- ZFYVE19 | c.1196G>T p.G399V (on ENST00000355341 / NM_001077268.2; = p.G389V on NM_032850.5) | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs761945689; called by muse, mutect2, varscan2
- ATIC | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- BAHD1 | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMYA5 | c.1613A>G p.E538G | Missense Mutation (SNP) | VAF 62/770 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2
- COL7A1 | c.6961G>T p.D2321Y | Missense Mutation (SNP) | VAF 81/868 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); called by muse, mutect2
- CYP17A1 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 87/775 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- FCGBP | c.8274G>C p.Q2758H | Missense Mutation (SNP) | VAF 75/706 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); called by muse, varscan2
- GCH1 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 76/614 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- HELZ | c.3757C>A p.L1253I | Missense Mutation (SNP) | VAF 74/839 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.341); called by muse, mutect2
- IQUB | c.397+2T>A p.X133_splice | Splice Site (SNP) | VAF 38/384 reads (10%) | called by muse, mutect2
- LRRIQ1 | c.4235G>C p.R1412P | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MASP1 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 70/660 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- MEF2B | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MYH2 | c.3610G>T p.D1204Y | Missense Mutation (SNP) | VAF 28/1134 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5M1 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 114/1455 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.12); called by muse, mutect2
- PTBP1 | c.1054C>G p.Q352E (on ENST00000349038 / NM_031991.4; = p.Q378E on NM_002819.5) | Missense Mutation (SNP) | VAF 50/652 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.063); called by muse, mutect2
- SLC4A1 | c.2365T>C p.F789L | Missense Mutation (SNP) | VAF 62/907 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2
- SOX13 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 160/633 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- STAB2 | c.5273A>G p.N1758S | Missense Mutation (SNP) | VAF 42/619 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- TREML2 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2
- TSPAN18 | c.64-1G>T p.X22_splice | Splice Site (SNP) | VAF 55/547 reads (10%) | called by muse, mutect2
- TSPYL4 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 50/467 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.10988C>A p.S3663Y | Missense Mutation (SNP) | VAF 62/996 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF215 | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 53/492 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF334 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AC098582.1 | c.2676C>A p.I892= | Silent (SNP) | VAF 78/828 reads (9%) | catalogued as rs1231322079; called by muse, mutect2
- ADGRA3 | c.393A>G p.L131= | Silent (SNP) | VAF 52/652 reads (8%) | catalogued as rs768923380; called by muse, mutect2
- DCHS1 | c.4608C>A p.V1536= | Silent (SNP) | VAF 71/567 reads (13%) | called by muse, mutect2, varscan2
- DIPK1B | c.972C>T p.T324= | Silent (SNP) | VAF 46/494 reads (9%) | catalogued as rs373675382, COSV100765493; called by muse, mutect2
- DXO | c.309G>A p.L103= | Silent (SNP) | VAF 75/798 reads (9%) | called by muse, mutect2
- FNDC1 | c.2295C>T p.S765= | Silent (SNP) | VAF 83/872 reads (10%) | catalogued as rs760746455; called by muse, mutect2
- GRM6 | c.1125G>A p.Q375= | Silent (SNP) | VAF 58/665 reads (9%) | called by muse, mutect2
- KIF22 | c.645C>A p.I215= | Silent (SNP) | VAF 86/672 reads (13%) | catalogued as COSV50713969; called by muse, mutect2, varscan2
- MFSD11 | c.507A>T p.R169= | Silent (SNP) | VAF 111/553 reads (20%) | called by muse, mutect2, varscan2
- MGAM | c.753C>T p.F251= | Silent (SNP) | VAF 79/731 reads (11%) | called by muse, mutect2, varscan2
- RGS20 | c.732C>A p.T244= (on ENST00000297313 / NM_170587.4; = p.T97= on NM_003702.4) | Silent (SNP) | VAF 90/1043 reads (9%) | catalogued as rs1264296262; called by muse, mutect2
- UBR3 | c.2793T>G p.T931= | Silent (SNP) | VAF 67/536 reads (13%) | called by muse, mutect2, varscan2
- ZNF506 | c.237T>G p.S79= | Silent (SNP) | VAF 40/316 reads (13%) | catalogued as COSV101475673; called by muse, mutect2, varscan2
- AP4S1 | c.294+41A>G | Intron (SNP) | VAF 38/572 reads (7%) | called by muse, mutect2
- CHL1 | c.679+949G>A | Intron (SNP) | VAF 44/445 reads (10%) | called by muse, mutect2, varscan2
- DNAH17 | c.12772-39C>A | Intron (SNP) | VAF 49/407 reads (12%) | called by muse, mutect2, varscan2
- DUSP14 | c.-58G>A | 5'UTR (SNP) | VAF 14/77 reads (18%) | called by mutect2, varscan2
- FAM104B | c.-3A>G | 5'UTR (SNP) | VAF 66/232 reads (28%) | catalogued as rs1337044498; called by muse, mutect2, varscan2
- IFT172 | c.1325+36A>C | Intron (SNP) | VAF 47/273 reads (17%) | called by muse, mutect2, varscan2
- MTRNR2L1 | c.-48G>A | 5'UTR (SNP) | VAF 38/387 reads (10%) | catalogued as rs148742901; called by muse, mutect2
- RNF130 | c.*11dup | 3'UTR (INS) | VAF 90/1036 reads (9%) | called by mutect2, pindel
- SLC17A7 | c.868-21G>T | Intron (SNP) | VAF 46/469 reads (10%) | called by muse, mutect2
- SYN1 | c.-98G>C | 5'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs989741899; called by muse, mutect2, varscan2
- TMEM161A | c.-21C>T | 5'UTR (SNP) | VAF 48/488 reads (10%) | called by muse, mutect2
